Somatic mutation profile of tumor specimen ALCH-B2DN-TTR1-A (aliquot ALCH-B2DN-TTR1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B2DN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.5 years (26,474 days).
Specimen ALCH-B2DN-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aabee5a5-09c7-431e-a01f-20e4aa2b1f13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2DN-NB1-A (Blood Derived Normal), aliquot ALCH-B2DN-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fef656d-3b29-4748-a96c-837bad885333

The open-access MAF lists 91 somatic variants for this specimen: 53 protein-altering or splice-affecting, 26 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 26, Intron 6, Nonsense Mutation 5, 5'UTR 4, Splice Region 2, 3'UTR 2, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59214349, COSV59219610; called by muse, mutect2
- AMPH | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272402161, COSV57740359; called by muse, mutect2
- ARID1A | c.6625C>T p.Q2209* | Nonsense Mutation (SNP) | VAF 18/217 reads (8%) | catalogued as COSV61372280; called by muse, mutect2
- BRD3 | c.1136A>G p.D379G | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57703482; called by muse, mutect2
- CPT1C | c.2306A>T p.K769M | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs1021039766; called by muse, mutect2, varscan2
- DDI1 | c.277C>A p.R93S | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV56386828; called by muse, mutect2
- DSG1 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 26/729 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57139144; called by muse, mutect2
- HSP90AB1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100807040; called by muse, mutect2, varscan2
- KIF16B | c.3731C>T p.P1244L | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734807; called by muse, mutect2
- LRP12 | c.1990A>G p.M664V | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1242163059; called by muse, mutect2
- LYNX1-SLURP2 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58187345; called by muse, mutect2
- MAP6 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs771037189; called by muse, mutect2
- MCTP1 | c.1935A>G p.G645= | Splice Region (SNP) | VAF 6/63 reads (10%) | catalogued as rs1407547825; called by muse, mutect2
- NAV3 | c.3571C>A p.P1191T | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57119984; called by muse, mutect2
- NCK1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 20/262 reads (8%) | catalogued as COSV56637012, COSV99999376; called by muse, mutect2
- OGDHL | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV65101725; called by muse, mutect2
- PCDHGA10 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 18/302 reads (6%) | catalogued as COSV53966962, COSV54011010; called by muse, mutect2
- PCDHGB1 | c.1133T>A p.V378E | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99534888; called by muse, mutect2
- PKD1L2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV61412922; called by muse, mutect2
- POTEC | c.103T>A p.C35S | Missense Mutation (SNP) | VAF 56/770 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV100743728; called by muse, mutect2
- RASSF9 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 11/240 reads (5%) | catalogued as COSV63433125; called by muse, mutect2
- TARS1 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 38/577 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV99465622; called by muse, mutect2
- UBOX5 | c.1529G>C p.R510P | Missense Mutation (SNP) | VAF 54/734 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99417888; called by muse, mutect2
- ZNF791 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as COSV58481312; called by muse, mutect2
- ZSCAN1 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 25/342 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.456); catalogued as rs779775559, COSV56607313; called by muse, mutect2
- ABCE1 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ACCSL | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 30/567 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ADGRD2 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- APCDD1L | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- BSN | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- C1orf35 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- CMA1 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 44/510 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.383); called by muse, mutect2
- CNTN5 | c.1622C>A p.A541D | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- COL3A1 | c.1253C>A p.P418Q | Missense Mutation (SNP) | VAF 103/1201 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2
- CYP4F2 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- DAAM1 | c.1976T>C p.F659S | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.105); called by muse, mutect2
- FAM126A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2
- GNA12 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GORASP1 | c.768C>T p.A256= | Splice Region (SNP) | VAF 34/624 reads (5%) | called by muse, mutect2
- IRS2 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- IVL | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 31/562 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); called by muse, mutect2
- LRRK1 | c.3623A>T p.H1208L | Missense Mutation (SNP) | VAF 66/483 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NTRK3 | c.2176-1G>T p.X726_splice (on ENST00000360948 / NM_001012338.2; = p.X712_splice on NM_002530.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 30/544 reads (6%) | called by muse, mutect2
- PDE11A | c.235A>T p.N79Y | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- RYR2 | c.9494C>T p.A3165V | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- SAGE1 | c.2700C>A p.H900Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SCP2 | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 13/373 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2
- SDCCAG8 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 14/373 reads (4%) | called by muse, mutect2
- SHPK | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- SOHLH2 | c.999A>T p.R333S | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2
- SOX15 | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- TRPM3 | c.925G>A p.V309M (on ENST00000357533 / NM_001366142.2; = p.V154M on NM_020952.6) | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.254); called by muse, mutect2
- UNC5D | c.809G>C p.R270T | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- ALDH1A3 | c.1356G>A p.L452= | Silent (SNP) | VAF 23/310 reads (7%) | catalogued as rs1199719762; called by muse, mutect2
- ANKRD6 | c.1065C>T p.A355= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as rs761191637; called by muse, mutect2
- C8B | c.459A>G p.A153= | Silent (SNP) | VAF 30/721 reads (4%) | called by muse, mutect2
- DKK3 | c.790C>A p.R264= | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as COSV100484917; called by muse, mutect2
- DSG1 | c.447T>C p.D149= | Silent (SNP) | VAF 84/571 reads (15%) | called by muse, mutect2, varscan2
- EHD4 | c.918G>T p.L306= | Silent (SNP) | VAF 34/517 reads (7%) | called by muse, mutect2
- FOSB | c.96C>T p.F32= | Silent (SNP) | VAF 24/262 reads (9%) | called by muse, mutect2
- GNB3 | c.783G>A p.L261= | Silent (SNP) | VAF 36/582 reads (6%) | called by muse, mutect2
- HOXA5 | c.84T>C p.S28= | Silent (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- KRT7 | c.684C>G p.L228= | Silent (SNP) | VAF 25/313 reads (8%) | called by muse, mutect2
- LTBR | c.351A>T p.T117= | Silent (SNP) | VAF 57/460 reads (12%) | called by muse, mutect2, varscan2
- MCOLN2 | c.1422G>A p.Q474= | Silent (SNP) | VAF 22/652 reads (3%) | called by muse, mutect2
- MPEG1 | c.1740C>T p.S580= | Silent (SNP) | VAF 26/273 reads (10%) | catalogued as rs186140164, COSV57092154; called by muse, mutect2
- MUC16 | c.29052C>A p.T9684= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as COSV67492363; called by muse, mutect2
- NAV1 | c.4509C>T p.P1503= | Silent (SNP) | VAF 46/442 reads (10%) | catalogued as rs769624749, COSV55224521; called by muse, mutect2
- NAV3 | c.4083G>A p.P1361= | Silent (SNP) | VAF 32/374 reads (9%) | catalogued as rs796840739, COSV57088121; called by muse, mutect2
- NBAS | c.5166A>G p.R1722= | Silent (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- PCDHGA5 | c.726C>T p.F242= | Silent (SNP) | VAF 12/317 reads (4%) | called by muse, mutect2
- PIK3CG | c.660C>A p.I220= | Silent (SNP) | VAF 36/443 reads (8%) | called by muse, mutect2
- PLCD4 | c.255C>T p.L85= | Silent (SNP) | VAF 37/510 reads (7%) | called by muse, mutect2
- PTCD2 | c.411G>A p.V137= | Silent (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- RYR1 | c.2229C>T p.I743= | Silent (SNP) | VAF 35/267 reads (13%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.420G>C p.V140= | Silent (SNP) | VAF 36/510 reads (7%) | catalogued as rs774709345; called by muse, mutect2
- SYNPO2 | c.591T>G p.V197= | Silent (SNP) | VAF 18/233 reads (8%) | catalogued as rs767183818; called by muse, mutect2
- SYT14 | c.732A>T p.G244= | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- TNC | c.3396G>A p.P1132= | Silent (SNP) | VAF 26/517 reads (5%) | catalogued as rs750372440, COSV100406447; called by muse, mutect2
- BRWD3 | c.1127+26A>G | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- CSMD3 | c.*2G>A | 3'UTR (SNP) | VAF 30/380 reads (8%) | catalogued as rs1239977200, COSV99849983; called by muse, mutect2
- DNMT1 | c.4245+32C>T | Intron (SNP) | VAF 31/354 reads (9%) | catalogued as rs374484590; called by muse, mutect2
- GATM | c.288+24C>T | Intron (SNP) | VAF 35/392 reads (9%) | called by muse, mutect2
- GMPR2 | c.857+58G>C | Intron (SNP) | VAF 9/140 reads (6%) | catalogued as rs1039642339; called by muse, mutect2
- ILK | c.89+39G>T | Intron (SNP) | VAF 38/408 reads (9%) | called by muse, mutect2
- LIN7A | c.82+51C>T | Intron (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- MPDU1 | c.*122G>A | 3'UTR (SNP) | VAF 46/725 reads (6%) | called by muse, mutect2
- NUDT1 | c.-14G>A | 5'UTR (SNP) | VAF 38/370 reads (10%) | called by muse, mutect2
- RAB27A | c.-14C>T | 5'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- RBM11 | c.-2G>A | 5'UTR (SNP) | VAF 38/296 reads (13%) | called by muse, mutect2, varscan2
- ZNF98 | c.-34T>A | 5'UTR (SNP) | VAF 25/362 reads (7%) | called by muse, mutect2
